Somatic mutation profile of tumor specimen MMRF_2525_1_BM_CD138pos (aliquot MMRF_2525_1_BM_CD138pos_T1_KHS5U_K15176) from MMRF case MMRF_2525, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 51.5 years (18,795 days).
Specimen MMRF_2525_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d4408a70-cbc6-49e5-a4e1-c895eec210b5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2525_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2525_1_PB_Whole_C3_KHS5U_K15175; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/97546553-48ed-45bd-b687-92081f813dae

The open-access MAF lists 73 somatic variants for this specimen: 20 protein-altering or splice-affecting, 15 silent, 38 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 25, Missense Mutation 15, Silent 15, Intron 10, Nonsense Mutation 3, 5'UTR 3, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGRN | c.3067C>T p.R1023* | Nonsense Mutation (SNP) | VAF 62/110 reads (56%) | catalogued as rs769541558; called by muse, mutect2, varscan2
- GNL1 | c.938G>A p.R313Q | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.573); catalogued as rs142734504; called by muse, mutect2, varscan2
- HCN1 | c.1660C>T p.R554* | Nonsense Mutation (SNP) | VAF 80/258 reads (31%) | catalogued as COSV57505579; called by muse, mutect2, varscan2
- HSPA9 | c.379C>T p.R127* | Nonsense Mutation (SNP) | VAF 42/103 reads (41%) | catalogued as COSV51864215; called by muse, mutect2, varscan2
- IGLL5 | c.127G>T p.V43F | Missense Mutation (SNP) | VAF 43/43 reads (100%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.041); catalogued as rs6003368, COSV73248992, COSV73250942, COSV73250989, COSV73251049; called by muse, mutect2, varscan2
- PTPRU | c.983G>A p.R328H | Missense Mutation (SNP) | VAF 84/192 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.021); catalogued as COSV60523095; called by muse, mutect2, varscan2
- RYR1 | c.3809G>A p.R1270H | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs762397196, COSV62113615; called by muse, varscan2
- SEMA4A | c.1960G>A p.A654T | Missense Mutation (SNP) | VAF 62/234 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV61772549; called by muse, mutect2, varscan2
- CRHBP | c.793T>C p.Y265H | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT tolerated (0.44); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- DNAH2 | c.4838T>C p.V1613A | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- FSIP2 | c.20383A>T p.S6795C | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGHV2-70D | c.304A>T p.T102S | Missense Mutation (SNP) | VAF 42/64 reads (66%) | SIFT tolerated (0.24); PolyPhen benign (0.062); called by muse, varscan2
- KLF15 | c.731A>G p.E244G | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MROH6 | c.40G>A p.A14T | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- PKHD1 | c.535A>G p.I179V | Missense Mutation (SNP) | VAF 42/130 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTPRB | c.634C>A p.L212M | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- RBM10 | c.2021A>G p.Q674R | Missense Mutation (SNP) | VAF 47/93 reads (51%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- SIAH2 | c.73C>G p.H25D | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRAF3 | c.1354del p.Y452Ifs*9 | Frame Shift Del (DEL) | VAF 46/67 reads (69%) | called by mutect2, pindel, varscan2
- ZNF254 | c.724del p.E242Nfs*17 | Frame Shift Del (DEL) | VAF 140/279 reads (50%) | called by mutect2, pindel, varscan2
- ADAD1 | c.1209T>C p.S403= | Silent (SNP) | VAF 66/130 reads (51%) | called by muse, mutect2, varscan2
- CACNA1B | c.3111G>A p.V1037= | Silent (SNP) | VAF 54/163 reads (33%) | called by muse, mutect2, varscan2
- DUSP2 | c.271C>T p.L91= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as rs545367330, COSV56620204; called by muse, mutect2, varscan2
- F2RL1 | c.318G>A p.K106= | Silent (SNP) | VAF 22/162 reads (14%) | called by muse, mutect2, varscan2
- GGT5 | c.237C>T p.S79= | Silent (SNP) | VAF 21/47 reads (45%) | catalogued as rs760496253, COSV99571513; called by muse, mutect2, varscan2
- IGHV1-69D | c.288C>T p.S96= | Silent (SNP) | VAF 71/76 reads (93%) | called by muse, mutect2, varscan2
- KIF14 | c.1251C>T p.Y417= | Silent (SNP) | VAF 45/163 reads (28%) | catalogued as rs199789511; called by muse, mutect2, varscan2
- NRXN2 | c.4797C>T p.G1599= | Silent (SNP) | VAF 30/98 reads (31%) | catalogued as rs773103045; called by muse, mutect2, varscan2
- OR10A5 | c.720T>C p.S240= | Silent (SNP) | VAF 216/340 reads (64%) | called by muse, mutect2, varscan2
- OR51M1 | c.120C>T p.F40= | Silent (SNP) | VAF 212/620 reads (34%) | called by muse, mutect2, varscan2
- PSMA1 | c.126T>C p.T42= | Silent (SNP) | VAF 56/183 reads (31%) | catalogued as COSV67165693; called by muse, mutect2, varscan2
- QSOX2 | c.1179C>T p.A393= | Silent (SNP) | VAF 24/111 reads (22%) | catalogued as rs563891508, COSV100699792; called by muse, mutect2, varscan2
- SNCAIP | c.1464C>T p.H488= | Silent (SNP) | VAF 74/79 reads (94%) | catalogued as rs931871716; called by muse, mutect2, varscan2
- SPOCK1 | c.426A>T p.A142= | Silent (SNP) | VAF 11/82 reads (13%) | called by muse, mutect2, varscan2
- TREX2 | c.741C>T p.R247= (on ENST00000334497; = p.R204= on NM_080701.3) | Silent (SNP) | VAF 60/100 reads (60%) | catalogued as rs140705385, COSV57849769; called by muse, mutect2, varscan2
- ABCB9 | c.2040+50G>A | Intron (SNP) | VAF 5/38 reads (13%) | catalogued as rs1349307964; called by muse, mutect2
- AC090517.4 | c.-44_-43del | 5'UTR (DEL) | VAF 39/138 reads (28%) | called by mutect2, pindel, varscan2
- AIPL1 | c.*1319G>T | 3'UTR (SNP) | VAF 55/182 reads (30%) | called by muse, mutect2, varscan2
- ANGPT1 | c.*1797T>C | 3'UTR (SNP) | VAF 41/83 reads (49%) | called by muse, mutect2, varscan2
- APH1B | c.*143C>T | 3'UTR (SNP) | VAF 26/85 reads (31%) | called by muse, mutect2, varscan2
- APOOL | c.*149T>G | 3'UTR (SNP) | VAF 22/45 reads (49%) | catalogued as rs1181936104; called by muse, mutect2, varscan2
- ARHGEF9 | c.*759A>C | 3'UTR (SNP) | VAF 32/72 reads (44%) | called by muse, mutect2, varscan2
- ATP8A2 | c.*1894A>C | 3'UTR (SNP) | VAF 28/32 reads (88%) | called by muse, mutect2, varscan2
- BOLA1 | c.-556G>A | 5'UTR (SNP) | VAF 8/19 reads (42%) | called by mutect2, varscan2
- C6orf52 | c.317-1034G>A | Intron (SNP) | VAF 15/49 reads (31%) | catalogued as rs552068650; called by muse, mutect2, varscan2
- CCL8 | c.*259A>G | 3'UTR (SNP) | VAF 56/88 reads (64%) | catalogued as rs1405946934; called by muse, mutect2
- CDCA5 | c.*937G>A | 3'UTR (SNP) | VAF 59/205 reads (29%) | called by muse, mutect2, varscan2
- CDK7 | c.297+183C>T | Intron (SNP) | VAF 21/56 reads (38%) | called by muse, mutect2, varscan2
- CLVS1 | c.-152+4281G>A | Intron (SNP) | VAF 64/163 reads (39%) | called by muse, mutect2, varscan2
- CSRNP3 | c.*5551T>G | 3'UTR (SNP) | VAF 59/133 reads (44%) | called by muse, mutect2, varscan2
- DAXX | c.*117T>A | 3'UTR (SNP) | VAF 12/173 reads (7%) | catalogued as rs1431513349; called by muse, mutect2
- DLG1 | c.483+10506A>C | Intron (SNP) | VAF 40/101 reads (40%) | called by muse, mutect2, varscan2
- FAAP20 | c.*67C>T | 3'UTR (SNP) | VAF 29/47 reads (62%) | catalogued as rs1187138770; called by muse, mutect2, varscan2
- GPATCH11 | c.*2682G>T | 3'UTR (SNP) | VAF 29/57 reads (51%) | called by muse, mutect2, varscan2
- GPSM1 | c.1207+193G>A | Intron (SNP) | VAF 6/87 reads (7%) | catalogued as rs1208027760; called by muse, mutect2
- HCRTR2 | c.*38T>G | 3'UTR (SNP) | VAF 61/108 reads (56%) | called by muse, mutect2, varscan2
- IGHV1-24 | c.-23C>T | 5'UTR (SNP) | VAF 15/18 reads (83%) | catalogued as rs782820335; called by muse, mutect2, varscan2
- ITSN1 | c.346+110T>G | Intron (SNP) | VAF 15/33 reads (45%) | called by muse, mutect2, varscan2
- KCTD16 | c.*1331C>A | 3'UTR (SNP) | VAF 33/69 reads (48%) | called by muse, mutect2, varscan2
- KIAA1958 | c.*3020T>C | 3'UTR (SNP) | VAF 36/81 reads (44%) | catalogued as rs1162937124; called by muse, mutect2, varscan2
- LSM11 | c.*286A>G | 3'UTR (SNP) | VAF 46/49 reads (94%) | called by muse, mutect2, varscan2
- MTMR7 | c.*1555T>C | 3'UTR (SNP) | VAF 18/34 reads (53%) | called by muse, mutect2, varscan2
- NHLRC2 | c.*8558A>T | 3'UTR (SNP) | VAF 23/58 reads (40%) | called by muse, mutect2, varscan2
- PGD | c.9-127del | Intron (DEL) | VAF 30/79 reads (38%) | called by mutect2, pindel, varscan2
- PHLPP1 | c.1899+24_1899+33del | Intron (DEL) | VAF 50/154 reads (32%) | called by mutect2, pindel, varscan2
- PTMA | c.46-792G>T | Intron (SNP) | VAF 47/85 reads (55%) | called by muse, mutect2, varscan2
- RAPGEF2 | c.*438C>T | 3'UTR (SNP) | VAF 19/48 reads (40%) | called by muse, mutect2
- RPS6KC1 | c.*1425G>A | 3'UTR (SNP) | VAF 76/130 reads (58%) | called by muse, mutect2, varscan2
- SASH1 | c.*3000_*3001insTTAATCTATTGGAAATCA | 3'UTR (INS) | VAF 15/44 reads (34%) | called by mutect2, varscan2
- SCARB2 | c.*736C>T | 3'UTR (SNP) | VAF 40/61 reads (66%) | called by muse, mutect2, varscan2
- SLC17A4 | c.*229C>A | 3'UTR (SNP) | VAF 13/49 reads (27%) | called by muse, mutect2, varscan2
- TNFRSF8 | c.*678C>T | 3'UTR (SNP) | VAF 126/260 reads (48%) | called by muse, mutect2, varscan2
- TXNDC5 | c.*574_*613del | 3'UTR (DEL) | VAF 41/227 reads (18%) | called by mutect2, pindel
